Somatic mutation profile of tumor specimen MP2PRT-PAVHLF-TMP1-A (aliquot MP2PRT-PAVHLF-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVHLF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.8 years (2,836 days).
Specimen MP2PRT-PAVHLF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0327d962-0867-4272-b314-71f47b1ddfbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHLF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHLF-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e571603-11f1-4ee3-bd63-df3c9121010c

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, In Frame Del 2, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLCNKA | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 172/457 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769265907; called by muse, mutect2, varscan2
- DEF8 | c.1006A>G p.M336V | Missense Mutation (SNP) | VAF 149/356 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.079); catalogued as rs762394914; called by muse, mutect2, varscan2
- DMC1 | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 102/254 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746644230; called by muse, mutect2, varscan2
- FNDC11 | c.517T>A p.F173I | Missense Mutation (SNP) | VAF 276/608 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as rs754786412; called by muse, mutect2, varscan2
- PRSS12 | c.125A>C p.H42P | Missense Mutation (SNP) | VAF 39/931 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs772710193; called by muse, mutect2
- PRSS38 | c.794G>C p.W265S | Missense Mutation (SNP) | VAF 229/605 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64540146; called by muse, mutect2, varscan2
- PTPRT | c.2248G>A p.V750M | Missense Mutation (SNP) | VAF 142/408 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs372713520, COSV61961422, COSV61995720; called by muse, mutect2, varscan2
- SPTAN1 | c.4976A>G p.K1659R | Missense Mutation (SNP) | VAF 69/334 reads (21%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs757109566; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKRD17 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 256/584 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP126 | c.2780A>G p.E927G | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- EBI3 | c.400G>C p.G134R | Missense Mutation (SNP) | VAF 178/417 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- FAP | c.1650del p.R550Sfs*59 | Frame Shift Del (DEL) | VAF 43/124 reads (35%) | called by mutect2, pindel, varscan2
- FGFR4 | c.1573A>G p.K525E | Missense Mutation (SNP) | VAF 176/326 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGKV1OR2-108 | c.350_352del p.P117del | In Frame Del (DEL) | VAF 25/99 reads (25%) | called by pindel*, varscan2
- MECOM | c.178del p.E60Rfs*33 | Frame Shift Del (DEL) | VAF 82/219 reads (37%) | called by mutect2, pindel, varscan2
- NPVF | c.539+1G>T p.X180_splice | Splice Site (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- PCLO | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 314/377 reads (83%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- PHF3 | c.1448C>G p.S483* | Nonsense Mutation (SNP) | VAF 29/72 reads (40%) | called by muse, mutect2, varscan2
- TRGJ1 | c.2_10delinsGGC p.N2_Y4delinsG | In Frame Del (DEL) | VAF 24/58 reads (41%) | called by pindel, varscan2*
- FAM13C | c.174C>T p.H58= | Silent (SNP) | VAF 188/430 reads (44%) | catalogued as rs758447924, COSV53246098, COSV53253453; called by muse, mutect2, varscan2
- FAM90A26 | c.105C>T p.P35= | Silent (SNP) | VAF 20/416 reads (5%) | called by muse, mutect2
- NAPRT | c.1368T>C p.P456= | Silent (SNP) | VAF 483/989 reads (49%) | called by muse, mutect2, varscan2
- SLC22A17 | n.1730C>T | RNA (SNP) | VAF 395/824 reads (48%) | catalogued as rs754473602; called by muse, mutect2, varscan2
